MMRF case MMRF_2002 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/18724e8a-1746-4420-8eba-eb716222722c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.1 years (25,986 days); ISS stage: II; Days to last known disease status: 106 days; Days to last follow up: 106 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 450 days (1.2 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 80 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 106.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.901 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 11 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 4.04 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.81 mg/dL.
- Day 80 (ECOG 0): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.069 mg/dL; Immunoglobulin G 3.29 g/L; Immunoglobulin A 4.94 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 4.33 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -18: Weight: 73 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_2002_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2002_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
